Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A15X, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A15X-01A (Primary Tumor).

[page 1 of 3]
1CB-0-3

Carcinoma, Serous, NOS

8441/3

12/9/10

Site Code: Endometrium

C54.1

Surgical Pathology

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 A11 J1 K1 L1 M1
N1 O1 P1 Q1
R1 S1 B1 B2 B3 B4 B5 B6 B7 B8 B9 T1 C1 C2 C3 C4 C5 C6 C7
D1 D2 D3 E1
E2 E3 F1 F2 F3 F4 G1 G2 G3 H1 I1
Uterus, right ovary (4.3 x 2.4 x 1.3 cm) with 9.3 cm
segment of
right fallopian tube, and left ovary (4.2 x 1.8 x 1.3 cm)
with 9.8
cm segment of left fallopian tube together weighing 195.0
grams;
portion of omentum (20.0 x 18.0 x 1.0 cm); right and left
pelvic
lymph nodes; right and left para-aortic lymph nodes above
and below
the inferior mesenteric artery; right gonadal vessels (9.0
cm in
length); left gonadal vessels (7.5 cm in length);
separately
submitted staging biopsies [cul de sac, bladder
peritoneum, left
colic gutter, right colic gutter, left pelvic sidewall,
right pelvic
sidewall, small bowel mesentery, large bowel mesentery,
and right
diaphragm (ranging in aggregate size from 0.8 cm to 2.0 cm
in
greatest dimension)]; and appendix (5.2 x 0.6 cm).

DIAGNOSIS:

Uterus, hysterectomy: FIGO grade III (of III) papillary
serous
carcinoma forming a polypoid mass (2.5 x 2.5 x 1.5 cm)
arising from
the lower uterine segment. No invasion is identified. A
benign
endometrial polyp (0.8 cm in greatest dimension) located
in the
anterior fundus. A single subserosal leiomyoma (3.0 cm in
greatest
dimension) and a single intramural (2.0 cm in greatest
dimension)

[page 2 of 3]
are also identified in the myometrium. The cervix is without diagnostic abnormality.

Ovary, left, oophorectomy: Corpus luteal cyst.

Ovary, right, oophorectomy: Endometriotic cysts.

Fallopian tube, left, salpingectomy: Benign paratubal cysts

(ranging in size from 0.5 cm to 2.0 cm in greatest dimension).

Fallopian tube, right, salpingectomy; Benign paratubal cysts

(ranging in size from 0.5 cm to 2.0 cm in greatest dimension).

Omentum, omentectomy: Negative for tumor.

Lymph nodes, right pelvic, excision: Multiple right pelvic lymph

nodes (1 external iliac, 4 internal iliac, 1 common iliac, 8 obturator) are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple left pelvic lymph

nodes (3 external iliac, 4 internal iliac, 3 common iliac, 5 obturator) are negative for tumor.

Lymph nodes, left and right para-aortic, excision: Multiple

para-aortic lymph nodes above the inferior mesenteric artery (4

left, 5 right) are negative for tumor. Multiple para-aortic lymph

nodes below the inferior mesenteric artery (3 left, 4 right) are negative for tumor.

Gonadal vessels, left and right, excision: The left and right

gonadal vessels are negative for tumor.

[page 3 of 3]
Soft tissue; cul de sac, bladder peritoneum, left colic gutter,
right colic gutter, left pelvic sidewall, right pelvic sidewall,
small bowel mesentery, large bowel mesentery, and right diaphragm;
staging biopsies: Negative for malignancy, all nine specimens

Appendix, appendectomy: Negative for malignancy .

ADDENDUM:

The neoplastic cells are positive for p53 and negative for WT-1,
confirming the H&E diagnosis.

ICDPA Discrepancy		☒
Met Malignancy History		☒

Source: NCI Genomic Data Commons file feed398a-3818-4513-8ce1-5761b234fc47 (TCGA-D1-A15X.F32EB1C9-4802-4873-8F0E-E10724DA9C15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).